MMRF case MMRF_1374 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ebccc0e8-d456-40fc-894a-1152d2f4c0cc

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Dead; Days to death: 354 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.4 years (26,086 days); ISS stage: II; Days to last known disease status: 354 days; Days to last follow up: 354 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 23 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 58 days; Days to treatment end: 58 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 59 days; Days to treatment end: 59 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 144 days; Days to treatment end: 183 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 319 days; Days to treatment end: 340 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 354.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -21 (ECOG 1): M Protein 3.74 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 160 mg/dL; Immunoglobulin G 51.1 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 5.38 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 4.53 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.43 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 148 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.53 mmol/L; Albumin 25 g/L; Total Protein 9.2 g/dL; Glucose 6.88 mmol/L; C-Reactive Protein 1.94 mg/dL.
- Day 81 (ECOG 2): M Protein 0.55 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.92 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.64 µg/mL; Lactate Dehydrogenase 4.63 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.84 ×10⁹/L; Platelets 79 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2 mmol/L; Albumin 25 g/L; Total Protein 5.3 g/dL; Glucose 5.39 mmol/L.
- Day 172 (ECOG 1): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.8 mg/dL; Immunoglobulin G 10 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.72 g/L; Beta 2 Microglobulin 2.83 µg/mL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.02 ×10⁹/L; Platelets 96 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.13 mmol/L; Albumin 30 g/L; Total Protein 6 g/dL; Glucose 5.5 mmol/L.
- Day 263 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12.1 mg/dL; Immunoglobulin G 16.2 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.78 g/L; Beta 2 Microglobulin 3.21 µg/mL; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 4.96 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.27 ×10⁹/L; Platelets 62 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.15 mmol/L; Albumin 27 g/L; Total Protein 6.2 g/dL; Glucose 5.45 mmol/L.
- Day 340 (ECOG 1): M Protein 1.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 685 mg/dL; Immunoglobulin G 18.1 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 12.8 µg/mL; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.88 ×10⁹/L; Platelets 10 ×10⁹/L; Creatinine 137 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 1.88 mmol/L; Albumin 18 g/L; Total Protein 5.8 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day -21: Weight: 99 kg; Height: 179 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (1 sample)
- Sample MMRF_1374_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -21 days.
